Gene-level copy-number profile of specimen HCM-BROD-0102-C71-85B from HCMI case HCM-BROD-0102-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.2 years (25,280 days).
Specimen HCM-BROD-0102-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d99a49a8-87ec-4aca-a22c-01b47526ba58.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0102-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/767fb240-3cdd-4964-b5f7-b7f1e8b64a20

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 575; copy number 2: 19,536; copy number 3: 32,850; copy number 4: 5,397; copy number 5: 34; copy number 6: 2; copy number 7: 3; copy number 9: 2; copy number 17: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,395,626–18,419,273, 2 genes, copy number 9: CR383658.2, BNIP3P6.
- chr21:44,172,169–44,194,338, 2 genes, copy number 17: AP001056.2, AP001056.1.
- chr21:44,217,014–44,244,993, 3 genes, copy number 7: ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 575. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
